CCDI case PBBWWW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/798f0699-729f-489a-ac63-6a1259ab2bfe

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.6 years (3,489 days).

Biospecimens (3 samples)
- Sample 0DJG71: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJG8R: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJGE2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
